Somatic mutation profile of tumor specimen TCGA-FS-A1ZQ-06A (aliquot TCGA-FS-A1ZQ-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZQ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 42.2 years (15,398 days).
Specimen TCGA-FS-A1ZQ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bce51ba9-c95a-4dc0-82ca-523d416e84b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZQ-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZQ-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1945d47b-6ebe-4f41-9a9e-b11388daefc1

The open-access MAF lists 580 somatic variants for this specimen: 362 protein-altering or splice-affecting, 205 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 329, Silent 205, Nonsense Mutation 22, Splice Site 7, Intron 5, RNA 4, Splice Region 3, 5'UTR 2, 5'Flank 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 106/145 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539219309, CM164821, COSV54369159; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 39/66 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- DHCR7 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs80338864, CM000700, CM993335, COSV62796209; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 51/141 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV61982533; called by mutect2, varscan2
- SCN1A | c.2575C>T p.R859C (on ENST00000303395 / NM_001202435.3; = p.R848C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121918784, CM065455, COSV57681333; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.3172G>C p.E1058Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV55939791; called by muse, mutect2, varscan2
- ABCD2 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58052050; called by muse, mutect2, varscan2
- ABHD13 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65535303; called by muse, mutect2, varscan2
- AC136428.1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as COSV101434981; called by muse, varscan2
- ACAN | c.4592G>A p.G1531E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754214360, COSV61366450; called by muse, mutect2, varscan2
- ACSM2B | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61657166; called by mutect2, varscan2
- ADAM18 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.461); catalogued as COSV55846469; called by muse, mutect2, varscan2
- ADAM2 | c.1356C>A p.C452* | Nonsense Mutation (SNP) | VAF 38/112 reads (34%) | catalogued as COSV55858883, COSV55866251; called by muse, mutect2, varscan2
- ADAM22 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1349217218, COSV55985746; called by muse, mutect2, varscan2
- ADAM28 | c.2006T>G p.V669G | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV56103600; called by muse, mutect2
- ADAM29 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537404539, COSV63660881; called by muse, mutect2, varscan2
- ADAM30 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 250/689 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV65561767; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as COSV99836223; called by muse, mutect2, varscan2
- ADAP2 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs368770576, COSV58297008; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV58441733, COSV58445613; called by muse, mutect2, varscan2
- AFP | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.247); catalogued as rs868639778, COSV56926466; called by mutect2, varscan2
- AGXT2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV51485171, COSV51486498; called by mutect2, varscan2
- AKAP11 | c.2965C>T p.P989S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV50295628; called by muse, mutect2, varscan2
- AL592490.1 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1490093990, COSV69427302; called by muse, mutect2, varscan2
- ANPEP | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV55593695; called by muse, mutect2, varscan2
- ARAP1 | c.1025C>T p.S342F (on ENST00000393609 / NM_001040118.2; = p.S97F on NM_015242.4) | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV61993658; called by muse, mutect2, varscan2
- ARAP2 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs756440781, COSV58290289; called by muse, mutect2, varscan2
- ARHGAP32 | c.6215C>T p.P2072L (on ENST00000310343 / NM_001378025.1; = p.P1723L on NM_014715.4) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV59853221; called by muse, mutect2, varscan2
- ARHGAP39 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs973591401, COSV52774381; called by mutect2, varscan2
- ARID4A | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62165747; called by muse, mutect2, varscan2
- ART5 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.102); catalogued as rs758940112, COSV51706274; called by muse, mutect2, varscan2
- ATP8A1 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52543943; called by muse, mutect2, varscan2
- ATP8A1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV52532212, COSV52539809; called by muse, mutect2, varscan2
- ATPSCKMT | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV54727466; called by muse, mutect2, varscan2
- BCAM | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV54304206; called by muse, mutect2, varscan2
- BEST3 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV58303978; called by muse, mutect2, varscan2
- BEST3 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1480403476, COSV56995534; called by muse, varscan2
- BRINP2 | c.1673A>C p.K558T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100838438, COSV100838572; called by muse, mutect2
- BRINP2 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV64179296; called by muse, mutect2, varscan2
- C11orf16 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778680108, COSV55148438, COSV55149435; called by muse, mutect2, varscan2
- C6 | c.2610G>A p.W870* | Nonsense Mutation (SNP) | VAF 110/287 reads (38%) | catalogued as COSV54707619; called by muse, mutect2, varscan2
- C7 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57470310, COSV57477578; called by muse, mutect2, varscan2
- C8A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs777495880, COSV63483150; called by mutect2, varscan2
- CACNA1E | c.1422A>C p.K474N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100704413; called by muse, mutect2
- CACNA1E | c.6326C>T p.A2109V (on ENST00000367573 / NM_001205293.3; = p.A2066V on NM_000721.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.091); catalogued as COSV62432290; called by muse, mutect2, varscan2
- CACNA1H | c.6814G>A p.D2272N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV52357043; called by muse, mutect2, varscan2
- CACNA1I | c.5792A>G p.N1931S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60815160; called by muse, mutect2, varscan2
- CACNG7 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs1484240015, COSV55816405; called by muse, mutect2, varscan2
- CASP5 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 56/98 reads (57%) | catalogued as COSV52830731; called by muse, mutect2, varscan2
- CAVIN4 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56867894; called by muse, mutect2, varscan2
- CCDC40 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV66477640; called by muse, mutect2, varscan2
- CCDC60 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs867385001, COSV59548206; called by muse, mutect2, varscan2
- CCDC7 | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.983); catalogued as COSV53233142; called by mutect2, varscan2
- CDH10 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.598); catalogued as rs770143615, COSV52584061, COSV52587606; called by mutect2, varscan2
- CDH18 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV56947923; called by muse, mutect2, varscan2
- CEMIP | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141395577, COSV54989253; called by muse, mutect2, varscan2
- CEP350 | c.3036A>T p.L1012F | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as COSV62607748; called by muse, mutect2, varscan2
- CEP350 | c.7451C>T p.S2484F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV62604894; called by muse, mutect2, varscan2
- CFAP92 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.484); catalogued as COSV54048507; called by muse, mutect2, varscan2
- CHRM2 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as COSV57780363; called by mutect2, varscan2
- CIAO3 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753565253, COSV52403751; called by muse, mutect2, varscan2
- CLCN7 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51972646; called by muse, mutect2, varscan2
- CLEC14A | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV60563846; called by muse, mutect2, varscan2
- CLEC5A | c.247T>A p.F83I | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV69397822; called by mutect2, varscan2
- CNGB3 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60695320; called by muse, mutect2, varscan2
- CNTN5 | c.2295G>A p.M765I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV54341408; called by mutect2, varscan2
- COL5A2 | c.1923+1G>A p.X641_splice | Splice Site (SNP) | VAF 40/115 reads (35%) | catalogued as COSV66412971; called by muse, mutect2, varscan2
- CPA3 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56046665; called by muse, mutect2, varscan2
- CPLANE1 | c.7882C>T p.P2628S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV57069559; called by muse, mutect2, varscan2
- CRB1 | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.946); catalogued as rs987199796, COSV66329024; called by muse, mutect2, varscan2
- CRNN | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs138795800, COSV55121876; called by mutect2, varscan2
- CRTC1 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs754042010, COSV58721814; called by muse, mutect2, varscan2
- CSMD1 | c.8461G>A p.G2821R (on ENST00000520002; = p.G2820R on NM_033225.6) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59320905; called by muse, mutect2
- CSMD1 | c.3212C>T p.S1071F (on ENST00000520002; = p.S1070F on NM_033225.6) | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs368592556, COSV59302376; called by muse, mutect2, varscan2
- CSMD1 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV101215030, COSV68238618, COSV68265654; called by mutect2, varscan2
- CTNNA3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65609127; called by muse, mutect2, varscan2
- CYP2F1 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100462610, COSV58528485; called by muse, mutect2, varscan2
- CYP4A11 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1477234945, COSV60224951; called by muse, varscan2
- CYRIA | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 53/143 reads (37%) | catalogued as COSV62866380; called by muse, mutect2, varscan2
- DBH | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55040834; called by muse, varscan2
- DCAF6 | c.2027+2T>C p.X676_splice (on ENST00000312263 / NM_001349778.1; = p.X696_splice on NM_018442.3 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV56582843; called by muse, mutect2
- DCC | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59123895; called by muse, mutect2, varscan2
- DCLRE1B | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56726353; called by muse, mutect2, varscan2
- DEFA4 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV52405211; called by mutect2, varscan2
- DEPDC1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV63958827; called by muse, mutect2, varscan2
- DGKG | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1263001967, COSV53961186; called by muse, varscan2
- DHRS12 | c.409G>A p.E137K (on ENST00000444610 / NM_001377930.1; = p.E88K on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.221); catalogued as COSV54472675; called by muse, mutect2, varscan2
- DHRS3 | c.872C>T p.T291I | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs779442997, COSV66108703; called by muse, mutect2, varscan2
- DIDO1 | c.6020C>T p.S2007L | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56615601; called by muse, mutect2, varscan2
- DNAH11 | c.9845A>T p.N3282I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV60972100; called by muse, mutect2, varscan2
- DNAH5 | c.12625C>T p.P4209S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868612793, COSV54201291; called by muse, mutect2, varscan2
- DNAH5 | c.11275G>A p.E3759K | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1349417589, COSV54243331; called by muse, mutect2, varscan2
- DNAH5 | c.10645G>A p.E3549K | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs267600360, COSV54210342; called by muse, mutect2, varscan2
- DNAH7 | c.10373T>C p.L3458P | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56761441, COSV56769921; called by muse, mutect2, varscan2
- DNAH7 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV56778308; called by mutect2, varscan2
- DNAH8 | c.7736G>A p.R2579Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576946348, COSV59444949; called by muse, mutect2, varscan2
- DRGX | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1403741977, COSV65137159; called by muse, mutect2, varscan2
- DSG3 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV57128407; called by mutect2, varscan2
- DSP | c.1420-1G>A p.X474_splice | Splice Site (SNP) | VAF 45/100 reads (45%) | catalogued as COSV65794514; called by muse, mutect2, varscan2
- DUOX2 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1436489952, COSV66533550; called by muse, mutect2, varscan2
- DYSF | c.855G>A p.T285= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as rs771253287, COSV50516514, COSV99246052; called by muse, mutect2
- ECT2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV51692218; called by muse, varscan2
- EFCAB6 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV53060762; called by muse, mutect2, varscan2
- EGF | c.3191C>T p.S1064L | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs966640587, COSV54478689; called by mutect2, varscan2
- EIF2AK4 | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.158); catalogued as COSV99775175; called by muse, mutect2, varscan2
- ENPEP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 42/122 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as COSV54453937; called by mutect2, varscan2
- EPG5 | c.7477C>T p.L2493F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56354107; called by muse, mutect2, varscan2
- EPHB4 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV62268151; called by muse, varscan2
- ERC2 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55649451; called by muse, mutect2, varscan2
- ESYT2 | c.2582C>T p.S861L (on ENST00000613624; = p.S785L on NM_020728.3) | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.527); catalogued as rs772089369, COSV51749641; called by mutect2, varscan2
- ETV6 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV67152800; called by muse, mutect2, varscan2
- FAM120B | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV53006963; called by muse, mutect2, varscan2
- FAM47A | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV60495968, COSV60498995; called by muse, mutect2, varscan2
- FAM83C | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65582100; called by muse, mutect2, varscan2
- FBXO22 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV57618384; called by muse, mutect2, varscan2
- FLG | c.5669C>T p.S1890F | Missense Mutation (SNP) | VAF 103/335 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs760939572, COSV64245892; called by muse, mutect2, varscan2
- FLG | c.4885G>A p.G1629S | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as COSV64245896; called by muse, mutect2, varscan2
- FLG | c.4652G>A p.G1551E | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as COSV64245901; called by muse, mutect2, varscan2
- FLG2 | c.4876G>A p.D1626N | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV66171469; called by muse, mutect2, varscan2
- FLG2 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV66171473; called by muse, mutect2, varscan2
- FLT1 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.934); catalogued as rs1464146066, COSV99164700; called by muse, mutect2, varscan2
- FNIP1 | c.242T>G p.V81G | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV57199127; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.761T>G p.I254S | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV58562069; called by muse, mutect2, varscan2
- FYB2 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.421); catalogued as COSV58586448; called by muse, mutect2, varscan2
- GABPB1 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 40/122 reads (33%) | catalogued as COSV55016868; called by mutect2, varscan2
- GCN1 | c.5896C>T p.P1966S | Missense Mutation (SNP) | VAF 88/112 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56112805; called by muse, varscan2
- GFRAL | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as rs541154071, COSV61232934; called by muse, mutect2, varscan2
- GIMAP6 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61034350; called by muse, mutect2, varscan2
- GLRB | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868460883, COSV52413855, COSV52423095; called by muse, mutect2, varscan2
- GPR84 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57210215; called by muse, mutect2, varscan2
- GPX5 | c.459+1G>A p.X153_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV69079759; called by muse, mutect2, varscan2
- GPX6 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs757259977, COSV62658657; called by muse, mutect2, varscan2
- GRIN3A | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62453117; called by mutect2, varscan2
- GSG1 | c.623C>T p.S208F (on ENST00000651961 / NM_001080555.4; = p.L213= on NM_031289.5) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52196513; called by muse, mutect2
- GSPT2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV61213617; called by mutect2, varscan2
- HBB | c.53A>C p.K18T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369865419, CM140701, COSV100092868; called by muse, mutect2, varscan2
- HCN1 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV57495620, COSV57543783; called by muse, mutect2, varscan2
- HEPH | c.2326C>T p.L776F (on ENST00000343002; = p.L509F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.79); PolyPhen benign (0.029); catalogued as COSV57969320; called by muse, mutect2, varscan2
- HERC1 | c.8696C>T p.S2899F | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV71249512, COSV71250935; called by muse, varscan2
- HERC1 | c.6779C>T p.S2260L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs200084879, COSV71249203; called by mutect2, varscan2
- HERC2 | c.10687G>A p.D3563N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV99875805; called by muse, mutect2, varscan2
- HFM1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV54020696; called by mutect2, varscan2
- HGF | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55952328; called by muse, mutect2, varscan2
- HOXA5 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs759617437, COSV56074388; called by muse, mutect2, varscan2
- HOXB5 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV53313895; called by muse, mutect2, varscan2
- HOXD3 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV50883839; called by muse, mutect2, varscan2
- HSD17B13 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100143275; called by muse, mutect2, varscan2
- HTR5A | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1359995825, COSV55280803; called by muse, mutect2, varscan2
- HYAL1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs370585179; called by muse, mutect2, varscan2
- HYDIN | c.14885C>T p.T4962I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as rs1193125051, COSV66641243; called by muse, mutect2, varscan2
- HYDIN | c.7743G>A p.W2581* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV59256374; called by muse, varscan2
- HYDIN | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs113898693, COSV55479229; called by mutect2, varscan2
- IARS2 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV56962645; called by muse, mutect2, varscan2
- IDO2 | c.97C>T p.L33= (on ENST00000389060; = p.L46= on NM_194294.2) | Splice Region (SNP) | VAF 4/9 reads (44%) | catalogued as rs1177723478, COSV58427186, COSV58427889; called by muse, mutect2, varscan2
- IGSF1 | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV63839227; called by muse, mutect2, varscan2
- IL21 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as rs1365973160, COSV52646813; called by muse, mutect2, varscan2
- ITGA10 | c.756C>T p.A252= | Splice Region (SNP) | VAF 11/51 reads (22%) | catalogued as COSV65198563; called by muse, mutect2, varscan2
- ITGAD | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.446); catalogued as COSV54932509; called by muse, mutect2, varscan2
- KATNIP | c.4211T>C p.F1404S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV55188461; called by muse, mutect2, varscan2
- KCNB2 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73051888; called by muse, mutect2, varscan2
- KCNN3 | c.1726G>A p.D576N (on ENST00000618040 / NM_001204087.1; = p.D561N on NM_002249.6) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV55217517, COSV55223503; called by muse, mutect2, varscan2
- KCTD21 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60741045, COSV60741616; called by muse, varscan2
- KDM3A | c.3076G>T p.G1026* | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as COSV57224475; called by mutect2, varscan2
- KIAA1109 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52676882; called by muse, varscan2
- KIF21B | c.2453A>C p.E818A | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100145059, COSV59763346; called by muse, mutect2, varscan2
- KIF6 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs531307501, COSV54688373; called by mutect2, varscan2
- KIFC1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV65737810; called by muse, mutect2, varscan2
- KMT2B | c.5830C>T p.P1944S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs780994590, COSV55866393; called by muse, mutect2
- KMT2C | c.3646G>A p.V1216I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs751399801, COSV51461863; called by mutect2, varscan2
- KNTC1 | c.5243C>G p.T1748R | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61082802; called by muse, mutect2, varscan2
- KRT24 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as rs201911699, COSV52881381; called by mutect2, varscan2
- KRT71 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57289338, COSV57293262; called by muse, mutect2, varscan2
- KRTAP17-1 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 14/21 reads (67%) | PolyPhen possibly damaging (0.446); catalogued as COSV61972480; called by muse, mutect2, varscan2
- LGSN | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV65728063; called by muse, mutect2
- LILRA1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs1260975687, COSV52183588; called by muse, mutect2, varscan2
- LILRB4 | c.1288C>A p.P430T (on ENST00000391733 / NM_001278428.3; = p.P429T on NM_001278426.3) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV54407602; called by muse, mutect2, varscan2
- LLGL2 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs150971482, COSV51386787; called by muse, varscan2
- LOXL2 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs765016338, COSV56120110; called by mutect2, varscan2
- LRBA | c.8203G>A p.E2735K | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1376055390, COSV63960612; called by muse, mutect2, varscan2
- LRFN2 | c.2355G>A p.M785I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV57832114; called by muse, mutect2, varscan2
- LRG1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs765306791, COSV56705348; called by mutect2, varscan2
- LRRC37B | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.259); catalogued as COSV58953961; called by muse, mutect2, varscan2
- LRRC3B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as rs1447656470, COSV67519995; called by muse, mutect2, varscan2
- LRRC6 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV51545755; called by muse, mutect2, varscan2
- LRRN1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253954205, COSV60012923; called by mutect2, varscan2
- LRTM1 | c.655A>T p.K219* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as rs1363073332, COSV55566639; called by mutect2, varscan2
- LSP1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100289063, COSV61136680; called by muse, mutect2, varscan2
- LUZP1 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 80/185 reads (43%) | catalogued as rs530578059, COSV56500065; called by muse, mutect2, varscan2
- LUZP2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138759346, COSV61213742; called by muse, mutect2, varscan2
- LYST | c.2834C>T p.S945F | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV67711472; called by muse, mutect2, varscan2
- MAGEA6 | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782130668, COSV61449314; called by muse, mutect2, varscan2
- MAGEB10 | c.23A>G p.K8R | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63312347; called by muse, mutect2, varscan2
- MBD5 | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV68698499; called by muse, mutect2, varscan2
- MCF2L2 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV61058962; called by muse, mutect2, varscan2
- MCPH1 | c.1115A>G p.K372R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV60917793; called by muse, mutect2, varscan2
- MED12L | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV56390863; called by muse, mutect2, varscan2
- MGAM | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.107); catalogued as rs1475463265, COSV71885216; called by muse, mutect2, varscan2
- MGAM | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs777169037, COSV72074491; called by muse, mutect2, varscan2
- MGLL | c.907C>T p.P303S (on ENST00000398104 / NM_001003794.2; = p.P313S on NM_007283.6) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs371143263; called by muse, mutect2, varscan2
- MGP | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.682); catalogued as COSV57454812; called by muse, mutect2, varscan2
- MIA2 | c.2155T>C p.F719L | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54497912; called by muse, mutect2
- MLIP | c.226T>A p.S76T | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.269); catalogued as COSV99230102; called by muse, mutect2, varscan2
- MROH2B | c.1447A>T p.K483* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV68187695; called by mutect2, varscan2
- MSR1 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs866802732, COSV50523295; called by muse, mutect2, varscan2
- MTCL1 | c.5027C>T p.P1676L (on ENST00000306329 / NM_001378206.1; = p.P1357L on NM_015210.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60409834; called by muse, mutect2, varscan2
- MTUS2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs759794648, COSV101462274, COSV70919464; called by muse, mutect2, varscan2
- MUC16 | c.17692C>T p.P5898S | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV67468056; called by muse, mutect2, varscan2
- MUC16 | c.10559C>T p.S3520L | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV67449114; called by muse, mutect2, varscan2
- MUC16 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs752724664, COSV67458170; called by muse, mutect2, varscan2
- NAALAD2 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV58964442; called by mutect2, varscan2
- NAV3 | c.6647G>A p.W2216* (on ENST00000397909 / NM_001024383.2; = p.W2194* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 41/63 reads (65%) | catalogued as COSV57102032; called by muse, mutect2, varscan2
- NBEA | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.098); catalogued as COSV59809816; called by muse, mutect2, varscan2
- NEURL4 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs773030979, COSV59761697; called by muse, mutect2, varscan2
- NKG7 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.279); catalogued as COSV52467289, COSV52467956; called by muse, mutect2, varscan2
- NKTR | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51774148; called by mutect2, varscan2
- NKX2-2 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs753385322, COSV65820122; called by mutect2, varscan2
- NLRP10 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV60781120; called by muse, mutect2, varscan2
- NLRP8 | c.3131C>T p.S1044F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as COSV52591799; called by muse, mutect2, varscan2
- NOTCH2 | c.1883G>A p.G628D | Missense Mutation (SNP) | VAF 116/343 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); catalogued as COSV56700704; called by muse, mutect2, varscan2
- NRAP | c.1407G>A p.M469I (on ENST00000359988 / NM_001322945.2; = p.M434I on NM_006175.4) | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1479563208, COSV63492975; called by mutect2, varscan2
- NUCB1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54387619; called by muse, mutect2, varscan2
- NWD1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV60348375; called by muse, mutect2, varscan2
- OLFML1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100206718, COSV100206804; called by muse, mutect2, varscan2
- OR10A4 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV65842302; called by muse, mutect2, varscan2
- OR10G9 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV66686612; called by muse, mutect2, varscan2
- OR2L8 | c.575G>A p.W192* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV61727746; called by muse, mutect2, varscan2
- OR2T12 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100527686, COSV58778387; called by mutect2, varscan2
- OR2Y1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 98/141 reads (70%) | catalogued as rs780001901, COSV57137600; called by muse, mutect2, varscan2
- OR2Z1 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.099); catalogued as COSV60693047; called by muse, mutect2, varscan2
- OR4A47 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.035); catalogued as rs267602921, COSV101487129, COSV71444871; called by muse, mutect2, varscan2
- OR4N2 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.865); catalogued as COSV100269859; called by mutect2, varscan2
- OR4N2 | c.590T>A p.L197H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100269860; called by mutect2, varscan2
- OR51B5 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1159995546, COSV100332621, COSV56176944; called by muse, mutect2, varscan2
- OR51G2 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV58994243; called by muse, varscan2
- OR51G2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs867001321, COSV58992760; called by muse, varscan2
- OR5K4 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs746411500, COSV100721422, COSV61584133; called by muse, mutect2, varscan2
- OR6C1 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.013); catalogued as COSV65574230; called by muse, mutect2, varscan2
- OTOGL | c.3568G>A p.E1190K (on ENST00000547103; = p.E1181K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV101509168, COSV72007126; called by muse, varscan2
- OTOL1 | c.1239C>G p.F413L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs755819960, COSV60007713; called by muse, mutect2, varscan2
- PACRGL | c.734C>T p.S245F (on ENST00000471979; = p.S218F on NM_145048.5) | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs989438410, COSV54844233; called by muse, mutect2, varscan2
- PADI3 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV64935107; called by muse, mutect2, varscan2
- PAPPA2 | c.3237-1G>A p.X1079_splice | Splice Site (SNP) | VAF 13/43 reads (30%) | catalogued as COSV62806865; called by muse, mutect2, varscan2
- PCDHA8 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 67/113 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV65339342; called by muse, mutect2, varscan2
- PCDHB14 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53390296, COSV99506216; called by muse, mutect2, varscan2
- PCED1B | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV101423681; called by muse, mutect2
- PCLO | c.14425G>A p.D4809N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV61639282; called by muse, mutect2, varscan2
- PCLO | c.10867C>T p.L3623F | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as COSV61639990; called by muse, mutect2, varscan2
- PCSK5 | c.2309C>T p.S770F | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV65093750; called by muse, mutect2, varscan2
- PDE1A | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1213395255, COSV59531459; called by muse, mutect2, varscan2
- PGM2L1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs865915174, COSV53348663; called by muse, mutect2, varscan2
- PIK3CG | c.2107A>T p.I703L | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV63251852; called by muse, mutect2, varscan2
- PIK3R5 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52657075; called by muse, mutect2, varscan2
- POGLUT1 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV55157923; called by muse, mutect2, varscan2
- POTEF | c.2229G>A p.M743I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV62543084; called by mutect2, varscan2
- PPM1G | c.1331+1G>A p.X444_splice | Splice Site (SNP) | VAF 42/131 reads (32%) | catalogued as COSV59771015; called by muse, mutect2, varscan2
- PPM1L | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV101534455, COSV72263334; called by muse, mutect2, varscan2
- PPP1R3A | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs62001880, COSV99492473; called by muse, mutect2, varscan2
- PPP1R9B | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as COSV57542149; called by muse, mutect2, varscan2
- PRB1 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.087); catalogued as COSV53707384; called by muse, mutect2, varscan2
- PRKCB | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV57777593; called by muse, varscan2
- PRKD2 | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV52188808; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1420C>T p.P474S (on ENST00000352766; = p.P395S on NM_181334.5) | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.958); catalogued as COSV61235854; called by muse, mutect2, varscan2
- PRSS38 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs200322609, COSV64541374; called by muse, mutect2, varscan2
- PSG1 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV54954832; called by muse, mutect2, varscan2
- PTGER3 | c.1191A>C p.E397D | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as COSV100657422, COSV63035603, COSV63040906; called by muse, mutect2
- PTK2 | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV61790053; called by mutect2, varscan2
- PTPRC | c.3811C>T p.L1271F | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV61418335; called by muse, mutect2, varscan2
- PTPRN2 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV67054683; called by muse, mutect2, varscan2
- PVRIG | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs560470511, COSV52781852; called by mutect2, varscan2
- PYHIN1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.401); catalogued as COSV63723554; called by muse, mutect2, varscan2
- RAB29 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV52521891; called by muse, mutect2, varscan2
- RALGPS2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as rs961943927, COSV100244217, COSV61340501; called by mutect2, varscan2
- RALGPS2 | c.638A>T p.D213V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100244218; called by muse, mutect2, varscan2
- RALYL | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.902); catalogued as COSV72824055; called by mutect2, varscan2
- RELN | c.10031G>A p.S3344N | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.613); catalogued as COSV59024708; called by muse, mutect2, varscan2
- RET | c.1442T>G p.L481R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV60689451; called by muse, mutect2
- RGS7 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58542273; called by muse, mutect2, varscan2
- ROS1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 182/279 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs1307627482, COSV63854873; called by muse, mutect2, varscan2
- RSRC1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV55835635; called by muse, mutect2, varscan2
- RSU1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV61714250; called by mutect2, varscan2
- RTL4 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 48/60 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100466204, COSV61205685; called by muse, mutect2, varscan2
- RYR2 | c.9059C>T p.S3020L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV63667804; called by mutect2, varscan2
- SACS | c.8141C>T p.S2714L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762610527, COSV66534432; ClinVar: uncertain significance; called by mutect2, varscan2
- SAMD9 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.169); catalogued as COSV66072928; called by muse, mutect2, varscan2
- SBF1 | c.4226C>T p.S1409F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV62369666; called by mutect2, varscan2
- SCN11A | c.5365C>T p.H1789Y | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs188441748, COSV56575310; called by muse, mutect2, varscan2
- SCN11A | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.723); catalogued as COSV56565789, COSV56567522; called by muse, mutect2, varscan2
- SDK1 | c.3439C>T p.R1147* | Nonsense Mutation (SNP) | VAF 80/244 reads (33%) | catalogued as rs750313949, COSV67357896; called by mutect2, varscan2
- SEL1L2 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53150443; called by muse, mutect2, varscan2
- SEMA4A | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV61772068; called by muse, mutect2, varscan2
- SERPINB2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.096); catalogued as COSV55093996; called by muse, mutect2, varscan2
- SEZ6L | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50675816; called by muse, mutect2, varscan2
- SGCZ | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs77000161, COSV66033585; called by mutect2, varscan2
- SLC12A9 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV51935863, COSV99308055; called by muse, mutect2, varscan2
- SLC17A6 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV99582058; called by muse, mutect2, varscan2
- SLC20A2 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV60605868; called by mutect2, varscan2
- SLC25A29 | c.676C>T p.P226S (on ENST00000359232 / NM_001039355.3; = p.P160S on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.102); catalogued as COSV63651379; called by muse, mutect2, varscan2
- SLC26A3 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs746185703, COSV60638639; called by muse, mutect2, varscan2
- SLC30A8 | c.778T>G p.L260V | Missense Mutation (SNP) | VAF 50/640 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV69974482, COSV69976771; called by muse, mutect2
- SLC36A1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54655630; called by muse, mutect2, varscan2
- SNUPN | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1401559654, COSV57949199; called by muse, mutect2, varscan2
- SON | c.5989C>T p.R1997C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as COSV51666833; called by muse, mutect2, varscan2
- SORT1 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 144/397 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56668708; called by muse, mutect2, varscan2
- SOX10 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61005922; called by mutect2, varscan2
- SPANXN2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs782127027, COSV65129080; called by muse, mutect2, varscan2
- SPATC1 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV66299602; called by muse, mutect2, varscan2
- SPHKAP | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60868618; called by muse, mutect2, varscan2
- STARD6 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57143159; called by mutect2, varscan2
- STRADB | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52045247; called by muse, mutect2, varscan2
- STRC | c.3713G>A p.R1238K | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101372226, COSV68660193; called by muse, mutect2, varscan2
- SULT1A1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV59086567; called by muse, mutect2, varscan2
- SYK | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs143341039; called by muse, mutect2, varscan2
- SYT10 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57343695; called by muse, mutect2, varscan2
- TATDN2 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 35/48 reads (73%) | catalogued as COSV55053309; called by muse, mutect2, varscan2
- TBC1D32 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.318); catalogued as COSV51550688; called by mutect2, varscan2
- TDRD5 | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV54248073; called by muse, mutect2, varscan2
- TENM4 | c.3965C>T p.A1322V | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs200340921, COSV53652402; called by muse, mutect2, varscan2
- TERF2IP | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.683); catalogued as rs760654243, COSV55613940; called by muse, mutect2, varscan2
- TMEM169 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs1203845063, COSV55265279; called by muse, mutect2, varscan2
- TNFRSF10D | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV57035056; called by muse, mutect2, varscan2
- TNXB | c.8336G>A p.G2779E (on ENST00000647633; = p.G2532E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.792); catalogued as COSV64485569; called by muse, mutect2, varscan2
- TRIM10 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64998523; called by muse, mutect2, varscan2
- TRIM46 | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); catalogued as COSV58117491; called by muse, mutect2, varscan2
- TRIM55 | c.1114A>T p.N372Y | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52549395; called by mutect2, varscan2
- TRIM61 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.229); catalogued as COSV61418698; called by mutect2, varscan2
- TSNAXIP1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs199807267, COSV66314580, COSV66315349; called by mutect2, varscan2
- TTC17 | c.2725C>T p.R909C | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs747480720, COSV50013740; called by muse, mutect2, varscan2
- TTN | c.89365G>A p.E29789K (on ENST00000591111; = p.E22365K on NM_003319.4) | Missense Mutation (SNP) | VAF 65/151 reads (43%) | PolyPhen possibly damaging (0.737); catalogued as rs868051341, COSV60244319; called by muse, mutect2, varscan2
- TTN | c.74079G>A p.W24693* (on ENST00000591111; = p.W17269* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as COSV60195965; called by muse, mutect2, varscan2
- TTN | c.31243G>A p.E10415K (on ENST00000591111; = p.E9488K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | PolyPhen benign (0.012); catalogued as rs374348069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.21709G>A p.E7237K (on ENST00000591111; = p.E6310K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/199 reads (34%) | PolyPhen possibly damaging (0.637); catalogued as COSV60244435; called by muse, mutect2, varscan2
- TTN | c.3804A>T p.E1268D (on ENST00000591111; = p.E1222D on NM_003319.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | PolyPhen benign (0.006); catalogued as COSV60244460; called by mutect2, varscan2
- TUBA3C | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as rs994945064, COSV68027701, COSV68028619; called by muse, mutect2, varscan2
- TXNDC2 | c.1159G>A p.G387S (on ENST00000306084 / NM_001098529.2; = p.G320S on NM_032243.6) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.247); catalogued as COSV60154826; called by muse, mutect2, varscan2
- UBE4A | c.2342C>T p.P781L (on ENST00000252108 / NM_001204077.2; = p.P788L on NM_004788.4) | Missense Mutation (SNP) | VAF 75/121 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV52806196; called by muse, mutect2, varscan2
- UBR4 | c.10646C>T p.S3549F | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64395986; called by muse, mutect2, varscan2
- UGT2B11 | c.1311-1G>A p.X437_splice | Splice Site (SNP) | VAF 14/58 reads (24%) | catalogued as COSV101485276; called by muse, varscan2
- USP16 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV57627124; called by muse, mutect2, varscan2
- USP50 | c.749C>T p.S250F (on ENST00000616326; = p.S241F on NM_203494.5) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs1198915212, COSV73214232; called by muse, mutect2, varscan2
- WDR72 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64745453; called by muse, varscan2
- WNK1 | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV60041923; called by muse, mutect2, varscan2
- WWP1 | c.1184G>A p.R395K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV55362536; called by muse, mutect2, varscan2
- XIRP2 | c.2462G>A p.G821E (on ENST00000628543; = p.G996E on NM_152381.6) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54708561; called by muse, mutect2, varscan2
- XKR6 | c.1285T>C p.C429R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100440996; called by muse, mutect2, varscan2
- XRCC1 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.088); catalogued as COSV53451813; called by muse, mutect2, varscan2
- ZAN | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV100770519, COSV61805947; called by muse, mutect2, varscan2
- ZAP70 | c.1547T>C p.F516S | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53856248; called by muse, mutect2, varscan2
- ZFHX4 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV50897029; called by muse, mutect2, varscan2
- ZFYVE26 | c.4457C>T p.P1486L | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61332009; called by muse, mutect2, varscan2
- ZNF184 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | catalogued as COSV53005188; called by muse, mutect2, varscan2
- ZNF230 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71273228; called by mutect2, varscan2
- ZNF425 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1346964822, COSV65202192; called by muse, mutect2, varscan2
- ZNF560 | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV56865962; called by muse, mutect2, varscan2
- ZNF676 | c.1591C>T p.H531Y (on ENST00000650058; = p.H499Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68094309; called by mutect2, varscan2
- ZNF71 | c.569A>T p.D190V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV60149375; called by muse, mutect2, varscan2
- ZNF804B | c.3325C>T p.H1109Y | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV60815291; called by mutect2, varscan2
- ZZEF1 | c.6094T>A p.S2032T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV67559427; called by muse, mutect2, varscan2
- FCGBP | c.6999T>A p.C2333* | Nonsense Mutation (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- FCGBP | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OPN1MW | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.4); PolyPhen benign (0.05); called by mutect2, varscan2
- SPATA31A1 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ABCA2 | c.5469C>T p.V1823= (on ENST00000614293; = p.V1793= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as rs367599305; called by mutect2, varscan2
- ABCC1 | c.3408C>T p.S1136= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs755141356, COSV60691357; called by muse, mutect2, varscan2
- ACOT11 | c.1464C>T p.F488= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs540502406, COSV56363361; called by mutect2, varscan2
- ACTR5 | c.1680G>A p.K560= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV54761779; called by muse, mutect2, varscan2
- ADAMTS7 | c.2748G>A p.Q916= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV66308851; called by muse, mutect2, varscan2
- ADCY1 | c.1767C>T p.T589= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs757763607, COSV52039768; called by muse, mutect2, varscan2
- AGAP1 | c.2247C>A p.I749= (on ENST00000304032 / NM_001037131.3; = p.I696= on NM_014914.5) | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV100366621; called by mutect2, varscan2
- AGAP1 | c.2248C>T p.L750= (on ENST00000304032 / NM_001037131.3; = p.L697= on NM_014914.5) | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100366623; called by muse, mutect2, varscan2
- ALDH2 | c.153G>A p.R51= | Silent (SNP) | VAF 42/60 reads (70%) | catalogued as COSV55670027; called by muse, varscan2
- ALPK2 | c.5754C>T p.I1918= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs766759599, COSV64495486; called by mutect2, varscan2
- AMBP | c.25T>C p.L9= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV54325056; called by muse, mutect2, varscan2
- ANO2 | c.342C>T p.F114= (on ENST00000356134 / NM_001278597.3; = p.F118= on NM_001278596.3) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs868713652, COSV59008935; called by muse, mutect2, varscan2
- AOC1 | c.156G>A p.K52= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV62870224; called by muse, mutect2, varscan2
- APCS | c.468G>A p.Q156= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs41317511, COSV54818113; called by muse, mutect2, varscan2
- APCS | c.516G>A p.E172= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV54818949; called by muse, mutect2, varscan2
- APEH | c.375G>A p.E125= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV56524595; called by muse, varscan2
- ARHGEF5 | c.2574C>T p.S858= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs1241614094, COSV50215517; called by muse, mutect2, varscan2
- ARL10 | c.198G>A p.E66= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV53799694; called by muse, mutect2, varscan2
- BRD1 | c.2964C>T p.L988= (on ENST00000216267 / NM_001349940.1; = p.L1119= on NM_001304808.3) | Silent (SNP) | VAF 73/179 reads (41%) | catalogued as rs568530542, COSV53457687; called by mutect2, varscan2
- BRD8 | c.2997G>A p.E999= | Silent (SNP) | VAF 41/62 reads (66%) | catalogued as COSV54730748; called by muse, mutect2, varscan2
- BSN | c.2310C>T p.A770= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as COSV56523506, COSV56524573; called by muse, varscan2
- BSN | c.5352C>T p.A1784= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV56524590; called by muse, mutect2, varscan2
- C9orf78 | c.204C>T p.P68= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as COSV59617257; called by muse, mutect2, varscan2
- CA6 | c.405C>T p.I135= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs750306584, COSV66262671; called by muse, mutect2, varscan2
- CACNG6 | c.627G>A p.P209= (on ENST00000252729 / NM_145814.1; = p.P138= on NM_031897.2) | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs1446689947, COSV53167649, COSV99403347; called by muse, mutect2, varscan2
- CALCRL | c.984C>T p.S328= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs765082504, COSV101130973, COSV66476474; called by muse, mutect2, varscan2
- CDCA2 | c.1395T>C p.F465= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV57947801; called by muse, mutect2, varscan2
- CFAP61 | c.222C>T p.P74= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV55641287; called by muse, mutect2, varscan2
- CMKLR1 | c.282C>T p.I94= (on ENST00000312143 / NM_001142344.2; = p.I92= on NM_004072.3) | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as rs560704906, COSV56440926; called by muse, mutect2, varscan2
- CNTN2 | c.369G>A p.R123= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV59351987; called by muse, mutect2, varscan2
- CNTNAP4 | c.3435G>A p.R1145= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV56694087, COSV56706692; called by mutect2, varscan2
- COL11A2 | c.414C>T p.V138= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as COSV59500622; called by muse, mutect2, varscan2
- COL8A1 | c.966G>A p.G322= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV53729061; called by muse, mutect2, varscan2
- COLQ | c.1036C>T p.L346= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as COSV101082100, COSV67525535; called by muse, mutect2, varscan2
- CSF2RB | c.1269G>A p.G423= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV53259990; called by muse, mutect2, varscan2
- CSMD2 | c.5490A>G p.E1830= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV53944002; called by muse, mutect2, varscan2
- CYP4Z1 | c.54C>T p.I18= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1444027021, COSV61966150; called by muse, mutect2, varscan2
- DAGLA | c.1494C>T p.S498= | Silent (SNP) | VAF 78/202 reads (39%) | catalogued as rs1212116120, COSV57194763; called by muse, mutect2, varscan2
- DAGLA | c.3057C>T p.I1019= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV57196228; called by muse, mutect2, varscan2
- DGKI | c.2088G>A p.R696= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs1359643821, COSV55967539; called by muse, mutect2, varscan2
- DHX34 | c.489C>T p.P163= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs1213836156, COSV60897281; called by muse, varscan2
- DHX34 | c.762C>T p.F254= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV60897295; called by muse, varscan2
- DMRTB1 | c.586C>T p.L196= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV65112614, COSV65113735; called by muse, mutect2, varscan2
- DNAAF5 | c.1353C>T p.S451= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs749145348, COSV52419911; called by muse, mutect2, varscan2
- DNAH10 | c.1173C>T p.F391= (on ENST00000409039; = p.F330= on NM_207437.3) | Silent (SNP) | VAF 82/110 reads (75%) | catalogued as rs1483261500, COSV68988876; called by muse, mutect2, varscan2
- DOT1L | c.2721C>T p.P907= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs749061261, COSV67112279; called by muse, mutect2, varscan2
- DRD5 | c.1014G>A p.E338= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs773496060, COSV58579686; called by muse, mutect2, varscan2
- DSG3 | c.1548G>A p.L516= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs1025859492, COSV57124741; called by mutect2, varscan2
- EIF2AK4 | c.1314C>T p.T438= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs754630320, COSV99775178; called by mutect2, varscan2
- EIF4E | c.426T>C p.F142= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1249297769, COSV55188464; called by muse, mutect2, varscan2
- EPHX1 | c.210C>T p.F70= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV55302981; called by muse, varscan2
- EVPL | c.6069C>T p.S2023= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs144079186; called by muse, mutect2, varscan2
- EVPL | c.4545G>A p.Q1515= | Silent (SNP) | VAF 62/125 reads (50%) | catalogued as COSV56914315; called by muse, mutect2, varscan2
- EVPL | c.2814G>A p.Q938= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV56914324; called by muse, mutect2, varscan2
- EYA2 | c.1305C>T p.I435= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV57948622; called by mutect2, varscan2
- F9 | c.1185C>T p.F395= | Silent (SNP) | VAF 65/80 reads (81%) | catalogued as CM032222, COSV54379990, COSV54381883; called by muse, mutect2, varscan2
- FAM234A | c.207C>T p.V69= | Silent (SNP) | VAF 93/244 reads (38%) | catalogued as rs1367291093, COSV56997012; called by muse, mutect2, varscan2
- FKBP15 | c.1524C>T p.L508= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV53037595, COSV53038069; called by mutect2, varscan2
- GALNT17 | c.189C>T p.V63= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV61180989; called by muse, mutect2
- GALNT5 | c.2145C>T p.I715= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs201738512, COSV52039942; called by muse, mutect2, varscan2
- GFRA1 | c.396C>T p.F132= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV100815704, COSV62609152; called by muse, varscan2
- GRK1 | c.378G>A p.L126= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV59553874; called by muse, mutect2
- GTF3C1 | c.3040C>T p.L1014= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV62243696; called by muse, varscan2
- HAO2 | c.1023C>T p.I341= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as COSV58037755; called by muse, mutect2, varscan2
- HECW2 | c.1527G>A p.E509= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV53669506; called by muse, mutect2, varscan2
- HERC2 | c.10686G>A p.G3562= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs371395759; called by muse, mutect2, varscan2
- HIP1R | c.426C>T p.S142= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as COSV53443719; called by muse, mutect2, varscan2
- HIVEP2 | c.6117C>T p.F2039= | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as COSV50036846; called by muse, mutect2, varscan2
- HOXA1 | c.165G>A p.V55= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs886062261, COSV56067374; ClinVar: uncertain significance; called by muse, mutect2
- HPS3 | c.363C>T p.F121= | Silent (SNP) | VAF 66/167 reads (40%) | catalogued as COSV56056540; called by mutect2, varscan2
- HS3ST3B1 | c.408G>A p.Q136= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV62907011; called by muse, mutect2
- HTR2C | c.585G>A p.R195= | Silent (SNP) | VAF 55/75 reads (73%) | catalogued as COSV52220414; called by muse, mutect2, varscan2
- HYDIN | c.6963G>A p.G2321= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1239696471, COSV99992864; called by mutect2, varscan2
- IFNLR1 | c.858C>T p.S286= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs573297615, COSV59526701; called by muse, mutect2, varscan2
- IGDCC4 | c.1527G>A p.L509= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV61538570; called by muse, mutect2, varscan2
- IGHV3-21 | c.15C>T p.L5= | Silent (SNP) | VAF 52/100 reads (52%) | called by muse, mutect2, varscan2
- IGLV3-27 | c.228C>T p.I76= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs765960933; called by muse, mutect2, varscan2
- IL1R2 | c.726C>T p.P242= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as COSV60208789; called by muse, mutect2, varscan2
- IL1RAP | c.156C>T p.H52= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV50767062; called by muse, mutect2, varscan2
- IPP | c.823C>T p.L275= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV63433400; called by muse, varscan2
- IQCJ-SCHIP1 | c.1473A>G p.K491= (on ENST00000485419 / NM_001197113.1; = p.K415= on NM_014575.3) | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV61850125, COSV61853542; called by muse, mutect2, varscan2
- KCNB1 | c.1236C>T p.I412= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs777806517, COSV65569418; called by mutect2, varscan2
- KCNK5 | c.669C>T p.Y223= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs763936853, COSV63989228, COSV63989229; called by muse, mutect2, varscan2
- KCNQ4 | c.444C>T p.I148= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs752503566, COSV61273570; called by muse, mutect2, varscan2
- KCTD14 | c.237C>T p.I79= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs775807284, COSV62001459; called by mutect2, varscan2
- KIF13A | c.1893C>T p.L631= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV52461362; called by muse, mutect2, varscan2
- KIR3DL2 | c.771G>A p.R257= | Silent (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.402G>A p.V134= | Silent (SNP) | VAF 56/156 reads (36%) | called by mutect2, varscan2
- KMO | c.1065G>A p.A355= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs566876281, COSV59362389; called by mutect2, varscan2
- KMT5B | c.2427G>A p.L809= | Silent (SNP) | VAF 74/201 reads (37%) | catalogued as COSV58568730; called by muse, mutect2, varscan2
- KNOP1 | c.33G>A p.G11= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV54929320; called by muse, mutect2, varscan2
- LDHC | c.660G>A p.T220= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs368187321; called by muse, mutect2, varscan2
- LGALS4 | c.592C>T p.L198= | Silent (SNP) | VAF 81/127 reads (64%) | catalogued as COSV57044637; called by muse, mutect2, varscan2
- LILRA1 | c.1146C>T p.F382= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV52183597; called by muse, mutect2, varscan2
- LRP1B | c.2826A>G p.R942= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV67256983; called by muse, mutect2, varscan2
- LRRN4 | c.1767G>A p.T589= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs370969415; called by muse, mutect2
- MAB21L4 | c.621G>A p.R207= (on ENST00000388934 / NM_001085437.3; = p.R39= on NM_024861.4) | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV56744277; called by muse, mutect2, varscan2
- MARK1 | c.540C>T p.H180= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as COSV65066706; called by muse, mutect2, varscan2
- MED12 | c.5217G>A p.L1739= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV61351064; called by muse, mutect2, varscan2
- MERTK | c.1566C>T p.S522= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV54933618, COSV99773926; called by muse, mutect2, varscan2
- MOGAT3 | c.414C>T p.F138= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV56176153; called by muse, mutect2, varscan2
- MROH9 | c.1134G>A p.E378= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV63011373; called by muse, mutect2, varscan2
- MRPS26 | c.162C>T p.F54= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs778372833, COSV55662133; called by mutect2, varscan2
- MUC16 | c.26337G>A p.T8779= | Silent (SNP) | VAF 38/56 reads (68%) | catalogued as rs768607433, COSV67482493; called by muse, mutect2, varscan2
- MUC5AC | c.1851C>T p.C617= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV62254994; called by muse, mutect2, varscan2
- MYNN | c.564C>T p.S188= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV62991964; called by muse, mutect2, varscan2
- MYO3B | c.2223C>T p.I741= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs866352729, COSV58712489; called by mutect2, varscan2
- MYO5C | c.4755G>A p.A1585= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs767148354, COSV55907408, COSV55912224; called by muse, mutect2, varscan2
- MYORG | c.702G>A p.A234= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs921800779, COSV52628041; called by muse, mutect2
- NAV3 | c.969C>T p.I323= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as COSV57102013, COSV99896554; called by muse, mutect2, varscan2
- NPHS1 | c.2913G>A p.Q971= | Silent (SNP) | VAF 51/100 reads (51%) | catalogued as COSV62289387; called by muse, mutect2, varscan2
- NPSR1 | c.468C>T p.F156= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as COSV62196839; called by muse, mutect2, varscan2
- NTF3 | c.48C>T p.I16= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs371107992; called by muse, mutect2, varscan2
- OLFML1 | c.522G>A p.K174= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs1396174543, COSV100206803; called by muse, mutect2, varscan2
- OR2F1 | c.891G>A p.V297= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV67331860; called by mutect2, varscan2
- OR2T3 | c.537C>T p.I179= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as rs965460968, COSV62083179; called by mutect2, varscan2
- OR4D5 | c.84C>T p.F28= | Silent (SNP) | VAF 46/66 reads (70%) | catalogued as COSV58308704; called by muse, mutect2, varscan2
- OR4K1 | c.225C>T p.N75= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as rs769564787, COSV53459632, COSV53461672; called by muse, mutect2
- OR5F1 | c.489C>T p.V163= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs759691323, COSV53547949; called by mutect2, varscan2
- OR6A2 | c.615C>T p.F205= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as rs865944663, COSV60264638; called by mutect2, varscan2
- P2RX6 | c.738C>T p.L246= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs1432870194, COSV60385424; called by mutect2, varscan2
- PADI1 | c.1143C>T p.F381= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs770038921, COSV64937691; called by muse, mutect2
- PAX1 | c.501G>A p.G167= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs1431156312, COSV68271452, COSV68272888; called by muse, mutect2, varscan2
- PCDHB11 | c.213G>A p.K71= | Silent (SNP) | VAF 50/68 reads (74%) | catalogued as COSV53382146; called by muse, mutect2, varscan2
- PCDHGB5 | c.210G>A p.S70= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs1206051880, COSV99547987; called by mutect2, varscan2
- PCED1B | c.1008T>A p.G336= | Silent (SNP) | VAF 35/416 reads (8%) | catalogued as COSV101423680; called by muse, mutect2
- PCIF1 | c.513C>T p.P171= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs771400958, COSV65026945; called by muse, mutect2, varscan2
- PCLO | c.7911G>A p.Q2637= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV61635588, COSV61655951; called by muse, mutect2, varscan2
- PCNX2 | c.3540C>T p.F1180= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs753792364, COSV50781615; called by mutect2, varscan2
- PDE6A | c.108C>T p.L36= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as COSV54930180; called by muse, mutect2, varscan2
- PEG3 | c.1632C>T p.F544= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as COSV55642868; called by mutect2, varscan2
- PGK2 | c.321C>T p.A107= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs1029425046, COSV59164932; called by muse, mutect2, varscan2
- PKD2 | c.2754C>T p.S918= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs748855749, COSV52940308; called by muse, mutect2, varscan2
- PKHD1L1 | c.4053G>A p.R1351= | Silent (SNP) | VAF 64/198 reads (32%) | catalogued as COSV65738454; called by muse, varscan2
- PKP2 | c.1470G>A p.R490= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV50741161; called by mutect2, varscan2
- PLCB4 | c.2940G>A p.E980= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV53802631; called by muse, varscan2
- PLRG1 | c.781C>T p.L261= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV57424405; called by muse, mutect2, varscan2
- PLXND1 | c.5502C>T p.I1834= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs770325056, COSV60717509; called by mutect2, varscan2
- POM121L12 | c.861C>T p.V287= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1410909831, COSV68692613; called by mutect2, varscan2
- POU4F2 | c.861G>A p.K287= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV55586117; called by muse, varscan2
- PPL | c.783G>A p.R261= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV62049558; called by muse, mutect2, varscan2
- PPP1R13L | c.1707C>T p.I569= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV62909276; called by muse, mutect2, varscan2
- PPP1R3A | c.2751C>T p.S917= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as rs1372121132, COSV52889575; called by muse, mutect2, varscan2
- PRAME | c.1029C>T p.S343= | Silent (SNP) | VAF 54/152 reads (36%) | catalogued as rs888976983, COSV67161744; called by muse, mutect2, varscan2
- PRODH2 | c.426C>T p.L142= (on ENST00000301175; = p.L66= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV56561234; called by muse, mutect2, varscan2
- PROKR1 | c.243C>T p.F81= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV58138308; called by mutect2, varscan2
- PRSS54 | c.1083G>A p.G361= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99541147; called by muse, mutect2, varscan2
- PRUNE2 | c.2076C>T p.S692= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV65045382; called by muse, mutect2, varscan2
- PSG2 | c.495G>A p.V165= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as COSV61544898, COSV61546017; called by mutect2, varscan2
- PSG8 | c.1143C>T p.I381= | Silent (SNP) | VAF 79/248 reads (32%) | catalogued as COSV60614256; called by muse, mutect2, varscan2
- PTPRB | c.363G>A p.E121= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as rs1264250178, COSV54249105; called by muse, mutect2, varscan2
- PTPRT | c.3213C>T p.F1071= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV61961893, COSV62006137; called by muse, varscan2
- PTPRU | c.168C>T p.I56= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs750516439, COSV60534052; called by muse, mutect2, varscan2
- PYGM | c.573G>A p.E191= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV51223841; called by muse, mutect2, varscan2
- RABEP2 | c.81C>T p.S27= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62870498; called by muse, mutect2, varscan2
- RDX | c.457C>T p.L153= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs757046736, COSV100563036; called by muse, mutect2, varscan2
- RDX | c.456C>T p.L152= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs919047877, COSV100563038; called by muse, mutect2, varscan2
- RNF43 | c.1419C>T p.G473= | Silent (SNP) | VAF 48/66 reads (73%) | catalogued as COSV68457506; called by muse, mutect2, varscan2
- RRAS | c.405C>T p.F135= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV55868951; called by muse, mutect2, varscan2
- RRP15 | c.273C>T p.G91= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV65118522; called by muse, mutect2, varscan2
- SALL1 | c.1722G>A p.E574= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV51755939; called by muse, mutect2, varscan2
- SDCCAG8 | c.1974G>A p.T658= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs1406874695, COSV59414525; called by muse, mutect2, varscan2
- SH2D3C | c.1269C>T p.T423= (on ENST00000314830 / NM_170600.3; = p.T266= on NM_005489.4) | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV59127917; called by muse, mutect2, varscan2
- SLC11A1 | c.357G>A p.K119= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV51918579; called by muse, mutect2, varscan2
- SLC12A9 | c.1827G>A p.G609= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV99308050; called by muse, mutect2, varscan2
- SLC24A1 | c.420G>A p.R140= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV56053389; called by mutect2, varscan2
- SLC44A2 | c.156C>T p.I52= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as COSV59838262; called by muse, mutect2, varscan2
- SLC4A1 | c.207G>A p.K69= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs267604902, COSV52262079; called by muse, varscan2
- SLC6A4 | c.1281C>T p.F427= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV55566477; called by muse, mutect2, varscan2
- SLCO1C1 | c.1764C>T p.A588= | Silent (SNP) | VAF 80/242 reads (33%) | catalogued as COSV56877324, COSV99858343; called by muse, varscan2
- SLFN12 | c.1200C>T p.F400= | Silent (SNP) | VAF 58/94 reads (62%) | catalogued as COSV59227133; called by muse, mutect2, varscan2
- SLIT2 | c.3546G>A p.T1182= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs1432886929, COSV56587284; called by mutect2, varscan2
- SMYD1 | c.939G>A p.L313= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV70225683; called by muse, mutect2, varscan2
- SRL | c.999C>T p.I333= | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as COSV68424070; called by muse, mutect2, varscan2
- STAB2 | c.4560C>T p.N1520= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as rs564431481, COSV66344203; called by muse, mutect2, varscan2
- STRN3 | c.426C>T p.N142= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV62581244; called by muse, mutect2, varscan2
- TMEM119 | c.270C>T p.F90= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs765267416, COSV67189161; called by muse, mutect2, varscan2
- TMEM39B | c.1002C>T p.L334= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV60380562; called by mutect2, varscan2
- TMEM62 | c.1113C>T p.P371= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV53042381; called by muse, mutect2, varscan2
- TNFRSF6B | c.105C>T p.T35= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV53928717; called by muse, mutect2, varscan2
- TRIM22 | c.646C>T p.L216= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs1255737960, COSV66091453; called by muse, mutect2, varscan2
- TRIML1 | c.1071C>T p.I357= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV60194111, COSV60194804; called by muse, mutect2, varscan2
- TRPM7 | c.1044C>T p.S348= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1405285486, COSV57920137; called by muse, mutect2, varscan2
- TTN | c.37782G>A p.V12594= (on ENST00000591111; = p.V5170= on NM_003319.4) | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV60244399; called by muse, mutect2, varscan2
- TTN | c.34674A>G p.E11558= (on ENST00000591111; = p.E10631= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/327 reads (10%) | catalogued as rs1004354766, COSV60244419; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.19533C>T p.I6511= (on ENST00000591111; = p.I5584= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs563320328, COSV60061177; called by mutect2, varscan2
- TTN | c.16443G>A p.G5481= (on ENST00000591111; = p.G4554= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/261 reads (30%) | catalogued as COSV59911578; called by muse, mutect2, varscan2
- TUBGCP6 | c.1689C>T p.F563= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs777886997, COSV50568300; called by mutect2, varscan2
- UBASH3B | c.246G>A p.L82= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV52499643; called by muse, mutect2, varscan2
- USP8 | c.258C>T p.F86= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV56167041; called by muse, mutect2, varscan2
- VCAN | c.4506C>T p.P1502= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV54112997; called by muse, mutect2, varscan2
- VPS50 | c.2235C>T p.F745= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs769077325, COSV59920148; called by muse, varscan2
- VWA3B | c.1332C>T p.V444= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs758732535, COSV68245448; called by muse, mutect2, varscan2
- WDFY3 | c.5487C>T p.V1829= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV55710193; called by muse, varscan2
- XKR6 | c.1284C>T p.F428= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100440999; called by muse, mutect2, varscan2
- YTHDC2 | c.687C>T p.F229= | Silent (SNP) | VAF 52/68 reads (76%) | catalogued as COSV50738030; called by muse, mutect2, varscan2
- ZBED1 | c.1794C>T p.F598= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as COSV58137417; called by muse, mutect2, varscan2
- ZBTB32 | c.240G>A p.G80= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV52891989; called by muse, mutect2, varscan2
- ZC4H2 | c.447C>T p.P149= | Silent (SNP) | VAF 20/26 reads (77%) | catalogued as COSV62005382; called by muse, mutect2, varscan2
- ZFP64 | c.1302C>T p.F434= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV53801922; called by mutect2, varscan2
- ZMIZ2 | c.1593C>T p.C531= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV54810127; called by muse, mutect2, varscan2
- ZNF208 | c.102A>G p.L34= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV68110735, COSV68113454; called by muse, mutect2, varscan2
- ZNF212 | c.348C>T p.N116= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as rs763408242, COSV60025771; called by muse, mutect2, varscan2
- ZNF711 | c.2076A>G p.K692= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV52157424; called by muse, mutect2, varscan2
- ZNFX1 | c.2079C>T p.T693= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs1206336771, COSV65577953; called by muse, mutect2, varscan2
- ADGRF2 | chr6:47687003 C>T | 3'Flank (SNP) | VAF 39/130 reads (30%) | catalogued as COSV57290793; called by muse, mutect2, varscan2
- CRYBB1 | c.-2C>T | 5'UTR (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99316136; called by muse, varscan2
- CTNNA2 | c.1057-79564G>A | Intron (SNP) | VAF 11/19 reads (58%) | catalogued as rs780662366, COSV100561656; called by muse, mutect2, varscan2
- DCHS2 | n.750G>A | RNA (SNP) | VAF 48/123 reads (39%) | catalogued as COSV59735477; called by muse, mutect2, varscan2
- DISC1 | c.1117+20570C>T | Intron (SNP) | VAF 18/62 reads (29%) | catalogued as COSV54423319; called by muse, mutect2, varscan2
- MIR517A | n.24G>A | RNA (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- NBPF25P | n.1561T>G | RNA (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- NTRK3 | c.1586-40584C>T | Intron (SNP) | VAF 28/72 reads (39%) | catalogued as rs1216517077, COSV100447472, COSV100447699; called by mutect2, varscan2
- STON2 | c.2784+72C>T | Intron (SNP) | VAF 49/125 reads (39%) | catalogued as COSV50850422; called by muse, mutect2, varscan2
- SUCO | chr1:172532500 C>T | 5'Flank (SNP) | VAF 25/48 reads (52%) | catalogued as rs1405121397, COSV55268891, COSV55271963; called by muse, mutect2, varscan2
- TTN | c.34264+5366G>A | Intron (SNP) | VAF 13/21 reads (62%) | catalogued as COSV100600551, COSV100623442; called by muse, mutect2, varscan2
- XIRP2 | c.-18G>A | 5'UTR (SNP) | VAF 26/77 reads (34%) | catalogued as COSV54701081; called by muse, mutect2, varscan2
- XIST | n.8222C>T | RNA (SNP) | VAF 30/36 reads (83%) | called by muse, mutect2, varscan2
